Somatic mutation profile of tumor specimen TCGA-17-Z058-01A (aliquot TCGA-17-Z058-01A-01W-0747-08) from TCGA case TCGA-17-Z058, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z058-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7aaf657-5f86-4959-9c6e-8d588646f532.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z058-11A (Solid Tissue Normal), aliquot TCGA-17-Z058-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06dbacda-e119-4e05-b65a-799d89dd1758

The open-access MAF lists 82 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Splice Site 5, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, In Frame Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC1 | c.4747G>A p.A1583T | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs760585060, COSV61975107; called by muse, mutect2
- BLK | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52055515, COSV52055587; called by muse, mutect2, varscan2
- CCDC7 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.999); catalogued as rs779750971, COSV53231248, COSV99511514; called by mutect2, varscan2
- DDX21 | c.1236+1G>T p.X412_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100826508; called by muse, mutect2, varscan2
- DDX27 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs558152082, COSV65629064; called by muse, mutect2, varscan2
- DNAJC7 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555646046, COSV57268340; called by muse, mutect2, varscan2
- FOXO3 | c.1112A>T p.D371V | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs879663859; called by muse, varscan2
- IRX5 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100315665; called by muse, mutect2, varscan2
- KLHL1 | c.302C>G p.T101R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs374390867; called by muse, mutect2, varscan2
- KLRK1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as rs750918291, COSV53698392; called by mutect2, varscan2
- LILRB2 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs779866193; called by muse, mutect2, varscan2
- LSAMP | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.066); catalogued as COSV61286188, COSV61301500; called by muse, mutect2
- MAEA | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT tolerated (0.59); PolyPhen benign (0.018); catalogued as COSV53263719; called by muse, mutect2, varscan2
- NOTCH2 | c.6547A>G p.M2183V | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs748538625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA5 | c.1573del p.E525Rfs*10 | Frame Shift Del (DEL) | VAF 20/25 reads (80%) | catalogued as COSV65349225; called by mutect2, pindel, varscan2
- RTN1 | c.1867G>T p.V623F | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50719439, COSV50747085; called by muse, mutect2, varscan2
- SHANK1 | c.6061C>T p.P2021S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs1036204984, COSV53264082; called by muse, mutect2, varscan2
- SPEG | c.8166C>A p.H2722Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV56665701; called by muse, varscan2
- ST6GALNAC1 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 43/216 reads (20%) | PolyPhen probably damaging (0.995); catalogued as COSV50082555; called by muse, mutect2, varscan2
- TP73 | c.186+1G>A p.X62_splice | Splice Site (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100601002; called by muse, mutect2, varscan2
- WWP1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as rs776225114; called by muse, mutect2, varscan2
- ZFPM2 | c.1861C>A p.L621I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV101022892; called by muse, mutect2, varscan2
- ZNF423 | c.46G>T p.E16* (on ENST00000563137 / NM_001379286.1; = p.E8* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 35/70 reads (50%) | catalogued as rs1555486219; called by muse, mutect2, varscan2
- ADAMTS17 | c.874-1G>T p.X292_splice | Splice Site (SNP) | VAF 24/38 reads (63%) | called by muse, varscan2
- ASMT | c.122del p.P41Qfs*13 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- ATF2 | c.886A>G p.K296E | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ATG2A | c.3694A>T p.N1232Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CARD11 | c.2761A>G p.I921V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH16 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CEP290 | c.6223C>A p.L2075M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); called by muse, mutect2
- CHGB | c.747C>A p.H249Q | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A3 | c.4897C>A p.L1633M | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2
- DNAH10 | c.11590C>A p.Q3864K (on ENST00000409039; = p.Q3803K on NM_207437.3) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN3 | c.3586+1_3586+9del p.X1196_splice | Splice Site (DEL) | VAF 29/77 reads (38%) | called by mutect2, pindel, varscan2
- FSCB | c.1357G>T p.A453S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, varscan2
- FSCB | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); called by muse, varscan2
- HAS3 | c.296A>C p.D99A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- IL1RL1 | c.1547A>T p.H516L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- KALRN | c.208A>G p.R70G | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- KIAA1549 | c.5098_5100del p.P1700del | In Frame Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, varscan2
- KIAA1549L | c.2114C>A p.T705K (on ENST00000321505; = p.T1002K on NM_012194.3) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.081); called by mutect2, varscan2
- LGALS9B | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPL37 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH9 | c.3596A>T p.E1199V | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- MYO5A | c.5160G>T p.R1720S | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PADI2 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- RPTOR | c.1882G>T p.G628C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- RYR1 | c.13638G>C p.E4546D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RYR2 | c.8279A>G p.Y2760C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC24A4 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC26A7 | c.462G>C p.L154F | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SRGN | c.454T>A p.L152I | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.079); called by muse, varscan2
- TBX15 | c.1024+1G>T p.X342_splice (on ENST00000369429 / NM_001330677.2; = p.X236_splice on NM_152380.3) | Splice Site (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- TBX15 | c.1024G>T p.G342* (on ENST00000369429 / NM_001330677.2; = p.G236* on NM_152380.3) | Nonsense Mutation (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- TERF1 | c.1066A>G p.R356G (on ENST00000276603 / NM_017489.3; = p.R336G on NM_003218.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, varscan2
- UPF1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.231); called by muse, varscan2
- ZNF256 | c.1403G>A p.C468Y | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, varscan2
- ZNF32 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ZNF550 | c.1075A>G p.I359V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF831 | c.2056G>T p.A686S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AOC3 | c.1203G>T p.G401= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV53823893; called by muse, mutect2, varscan2
- CD8B | c.498A>T p.P166= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- CDK19 | c.1185G>T p.A395= | Silent (SNP) | VAF 68/100 reads (68%) | called by mutect2, varscan2
- CLCNKA | c.1740C>T p.P580= | Silent (SNP) | VAF 15/18 reads (83%) | catalogued as rs1203016156; called by muse, mutect2, varscan2
- LIPE | c.2475C>A p.S825= | Silent (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- MTMR12 | c.2235G>A p.G745= | Silent (SNP) | VAF 55/86 reads (64%) | catalogued as rs1161711437; called by muse, mutect2, varscan2
- NAA11 | c.636T>C p.S212= | Silent (SNP) | VAF 24/25 reads (96%) | called by muse, mutect2, varscan2
- NQO1 | c.768G>A p.V256= | Silent (SNP) | VAF 17/221 reads (8%) | called by muse, mutect2
- RABGGTB | c.18G>A p.K6= | Silent (SNP) | VAF 36/234 reads (15%) | called by muse, varscan2
- SLC4A1 | c.78C>A p.I26= | Silent (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- SRP54 | c.597C>T p.D199= | Silent (SNP) | VAF 60/135 reads (44%) | called by muse, varscan2
- ST6GALNAC1 | c.921C>A p.S307= | Silent (SNP) | VAF 41/214 reads (19%) | called by muse, mutect2, varscan2
- TANC1 | c.5226C>G p.R1742= | Silent (SNP) | VAF 47/88 reads (53%) | called by muse, mutect2, varscan2
- TELO2 | c.609C>T p.L203= | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2
- TSKS | c.1416G>A p.L472= | Silent (SNP) | VAF 72/149 reads (48%) | catalogued as COSV99882929; called by muse, mutect2, varscan2
- ZNF629 | c.2175C>T p.L725= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152446131 C>A | 3'Flank (SNP) | VAF 37/77 reads (48%) | called by mutect2, varscan2
- FAM169B | n.517C>T | RNA (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- GALNT10 | c.568+17479G>T | Intron (SNP) | VAF 36/63 reads (57%) | called by muse, mutect2, varscan2
- UNG | c.133-40G>T | Intron (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- USH1C | c.1646+1119C>A | Intron (SNP) | VAF 80/155 reads (52%) | catalogued as COSV50015664; called by muse, mutect2, varscan2
